Somatic mutation profile of tumor specimen C3N-02290-01 (aliquot CPT0187010006) from CPTAC case C3N-02290, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 51.7 years (18,896 days).
Specimen C3N-02290-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f080f537-fb8f-4e57-a79f-00e95eab11d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02290-31 (Blood Derived Normal), aliquot CPT0187070002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37b1636a-f150-4925-b96f-46981a03ea3e

The open-access MAF lists 393 somatic variants for this specimen: 269 protein-altering or splice-affecting, 76 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 233, Silent 76, Nonsense Mutation 18, Intron 17, 3'UTR 10, RNA 9, 3'Flank 6, Frame Shift Del 6, Splice Site 6, 5'UTR 5, Splice Region 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 396/676 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397507546, CM086897, CM115675, CM1314033, COSV61004973, COSV61005158, COSV61008174; ClinVar: other / likely pathogenic; called by mutect2, varscan2
- ACTA2 | c.993C>A p.I331= | Splice Region (SNP) | VAF 100/370 reads (27%) | catalogued as COSV56515556; called by muse, mutect2, varscan2
- ADGRL3 | c.674C>A p.A225E (on ENST00000506720 / NM_001322402.2; = p.A157E on NM_015236.6) | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV72268675; called by muse, mutect2
- ANKRD17 | c.298G>C p.G100R | Missense Mutation (SNP) | VAF 68/402 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV58220263; called by muse, mutect2, varscan2
- ANTXR1 | c.1089+1del | Frame Shift Del (DEL) | VAF 35/310 reads (11%) | catalogued as COSV58021501; called by pindel, varscan2
- ASTN1 | c.661C>A p.R221S | Missense Mutation (SNP) | VAF 83/343 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99029691; called by muse, mutect2, varscan2
- ATM | c.7280T>G p.L2427R | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1555122272, COSV53729082, COSV53759952; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2A3 | c.2578G>A p.A860T | Missense Mutation (SNP) | VAF 58/302 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs762908744, COSV59226558; called by muse, mutect2, varscan2
- ATXN3L | c.649G>T p.D217Y | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as COSV101019382; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4189G>T p.D1397Y | Missense Mutation (SNP) | VAF 43/234 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV63246275; called by muse, mutect2, varscan2
- C10orf71 | c.1250C>A p.P417H | Missense Mutation (SNP) | VAF 51/195 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV100109579; called by muse, mutect2, varscan2
- C11orf53 | c.841T>A p.S281T | Missense Mutation (SNP) | VAF 92/192 reads (48%) | SIFT tolerated (0.89); PolyPhen benign (0.03); catalogued as rs973423827; called by muse, mutect2, varscan2
- C12orf56 | c.47G>T p.R16L | Missense Mutation (SNP) | VAF 75/238 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs374883655; called by muse, mutect2, varscan2
- CCDC170 | c.1400A>G p.Q467R | Missense Mutation (SNP) | VAF 56/336 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760911963; called by muse, mutect2, varscan2
- CD5L | c.451G>A p.V151M | Missense Mutation (SNP) | VAF 61/433 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs199701364; called by muse, mutect2, varscan2
- CEACAM18 | c.851C>G p.S284W | Missense Mutation (SNP) | VAF 157/388 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.143); catalogued as COSV67281998; called by muse, mutect2, varscan2
- CENPE | c.2402C>T p.T801I | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as rs1194769233; called by muse, mutect2
- CFH | c.3616del p.R1206Vfs*65 | Frame Shift Del (DEL) | VAF 50/220 reads (23%) | catalogued as CM100539, COSV66410739; called by mutect2, varscan2
- CHRM2 | c.821G>T p.C274F | Missense Mutation (SNP) | VAF 86/316 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as COSV57782609; called by muse, mutect2, varscan2
- COG1 | c.2852G>A p.G951D | Missense Mutation (SNP) | VAF 76/798 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs747128241; called by muse, mutect2
- COL3A1 | c.532C>A p.P178T | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.423); catalogued as COSV58586795; called by muse, mutect2, varscan2
- CORO2B | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs535068266, COSV99962985; called by muse, mutect2, varscan2
- CSMD1 | c.8830C>A p.R2944S (on ENST00000520002; = p.R2943S on NM_033225.6) | Missense Mutation (SNP) | VAF 90/318 reads (28%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.928); catalogued as COSV59318142; called by muse, varscan2
- DBI | c.64G>A p.D22N (on ENST00000355857 / NM_001079862.3; = p.D39N on NM_020548.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/218 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.26); catalogued as rs1237033928; called by muse, mutect2, varscan2
- DHX57 | c.1577G>T p.R526L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.061); catalogued as COSV54882914, COSV54889599; called by muse, mutect2, varscan2
- DRGX | c.433C>A p.P145T | Missense Mutation (SNP) | VAF 60/222 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.335); catalogued as COSV65135685; called by muse, mutect2, varscan2
- DUSP22 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV60529093; called by muse, mutect2
- DVL2 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 91/255 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); catalogued as rs780150593; called by muse, mutect2
- DYNC1I1 | c.793G>T p.G265W | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV61457929; called by muse, mutect2, varscan2
- EMX2 | c.202G>T p.D68Y | Missense Mutation (SNP) | VAF 110/375 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs1006487322, COSV71294637; called by muse, mutect2, varscan2
- FAM117A | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 109/529 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53633762; called by muse, mutect2, varscan2
- FASTKD5 | c.1709T>C p.L570P | Missense Mutation (SNP) | VAF 32/196 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1199042353; called by muse, mutect2, varscan2
- FBXL7 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 76/638 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.67); catalogued as rs775944574, COSV61640916, COSV61651772; called by muse, mutect2, varscan2
- FBXL7 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 50/405 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs562012884, COSV61640843; called by muse, mutect2, varscan2
- FMN2 | c.2296C>A p.R766S | Missense Mutation (SNP) | VAF 184/466 reads (39%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as COSV100146631; called by muse, mutect2, varscan2
- FOXG1 | c.848A>T p.K283M | Missense Mutation (SNP) | VAF 63/316 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57398562; called by muse, mutect2, varscan2
- GRIN2B | c.3559C>A p.H1187N | Missense Mutation (SNP) | VAF 146/355 reads (41%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.342); catalogued as COSV74206844; called by muse, mutect2, varscan2
- HAO1 | c.890G>T p.G297V | Missense Mutation (SNP) | VAF 46/339 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66491419; called by muse, mutect2, varscan2
- HDGF | c.164+1G>T p.X55_splice | Splice Site (SNP) | VAF 28/270 reads (10%) | catalogued as COSV61978211; called by muse, mutect2
- HR | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 78/222 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.162); catalogued as COSV100455734; called by muse, mutect2, varscan2
- ITGA11 | c.1147G>T p.G383* | Nonsense Mutation (SNP) | VAF 94/230 reads (41%) | catalogued as COSV100241091, COSV59877113; called by muse, mutect2, varscan2
- ITIH2 | c.1655C>T p.T552M | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV64435111; called by muse, mutect2, varscan2
- JPH3 | c.56G>T p.W19L | Missense Mutation (SNP) | VAF 240/634 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52467839; called by muse, mutect2, varscan2
- KCNAB3 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 58/379 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as rs1202228633; called by muse, mutect2, varscan2
- KCNH7 | c.1129-1G>T p.X377_splice | Splice Site (SNP) | VAF 7/60 reads (12%) | catalogued as rs753291958; called by muse, mutect2, varscan2
- KIF1A | c.457C>G p.R153G | Missense Mutation (SNP) | VAF 76/356 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756309359; called by muse, mutect2, varscan2
- KIRREL3 | c.1556C>A p.S519* | Nonsense Mutation (SNP) | VAF 151/308 reads (49%) | catalogued as COSV69383951; called by muse, mutect2, varscan2
- KLHL32 | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65112020; called by muse, mutect2, varscan2
- KMO | c.1408C>G p.P470A | Missense Mutation (SNP) | VAF 51/182 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV59362332; called by muse, mutect2, varscan2
- KRT77 | c.1271C>A p.A424E | Missense Mutation (SNP) | VAF 220/398 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59239659; called by muse, mutect2, varscan2
- LRP1B | c.13376C>A p.T4459N | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV67256548; called by muse, varscan2
- LRP1B | c.1690C>T p.H564Y | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV67230234; called by muse, mutect2
- LRP6 | c.1690G>A p.E564K | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as COSV53787212; called by muse, varscan2
- MAP3K4 | c.4090G>T p.D1364Y | Missense Mutation (SNP) | VAF 60/279 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62329815, COSV62334286; called by muse, mutect2, varscan2
- MEIS1 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 43/300 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV55486377; called by muse, mutect2, varscan2
- MSR1 | c.1223-1G>T p.X408_splice | Splice Site (SNP) | VAF 14/102 reads (14%) | catalogued as COSV100026839, COSV50537910; called by muse, mutect2, varscan2
- MUC16 | c.17833G>A p.A5945T | Missense Mutation (SNP) | VAF 45/235 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs199743326, COSV67499634; called by muse, mutect2, varscan2
- MUC17 | c.9416C>G p.S3139C | Missense Mutation (SNP) | VAF 51/267 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV60280850; called by muse, mutect2, varscan2
- MUC4 | c.7631C>G p.S2544C | Missense Mutation (SNP) | VAF 458/1614 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.709); catalogued as rs771042444; called by muse, mutect2, varscan2
- MUC4 | c.7415C>T p.S2472L | Missense Mutation (SNP) | VAF 456/2418 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.316); catalogued as rs1227451227, COSV100641515; called by muse, varscan2
- NEDD9 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 37/231 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs200144366, COSV101060836; called by muse, mutect2, varscan2
- NOS2 | c.3364C>T p.R1122C | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1246671724, COSV58223531; called by muse, mutect2, varscan2
- NPAS3 | c.2662G>A p.A888T (on ENST00000356141 / NM_001164749.2; = p.A856T on NM_022123.3) | Missense Mutation (SNP) | VAF 94/932 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs902489489, COSV100640438; called by muse, mutect2, varscan2
- NRXN1 | c.3683T>A p.V1228E | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV60525552; called by muse, mutect2, varscan2
- OPN4 | c.1117G>T p.G373C | Missense Mutation (SNP) | VAF 90/291 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV99618900; called by muse, mutect2, varscan2
- OR12D3 | c.743G>A p.C248Y | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0.296); catalogued as rs1312792568; called by muse, mutect2, varscan2
- OR2AK2 | c.875T>C p.L292P | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV63553633; called by muse, mutect2, varscan2
- OSCAR | c.32C>A p.T11N | Missense Mutation (SNP) | VAF 77/204 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.471); catalogued as COSV52928559; called by muse, mutect2, varscan2
- PABPC3 | c.873C>A p.Y291* | Nonsense Mutation (SNP) | VAF 15/123 reads (12%) | catalogued as rs770801283; called by muse, mutect2, varscan2
- PAX3 | c.1250G>A p.G417E | Missense Mutation (SNP) | VAF 68/300 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); catalogued as COSV100398904, COSV100399936; called by muse, mutect2, varscan2
- PAX5 | c.800T>C p.M267T | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as rs771833415; called by muse, mutect2, varscan2
- PDZRN3 | c.2004C>A p.S668R | Missense Mutation (SNP) | VAF 146/336 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.045); catalogued as rs921006712; called by muse, mutect2, varscan2
- PKD2L1 | c.2248G>A p.V750M | Missense Mutation (SNP) | VAF 88/321 reads (27%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as rs760940072, COSV100559242; called by muse, mutect2, varscan2
- PKHD1L1 | c.4927G>T p.A1643S | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV65749712; called by muse, mutect2, varscan2
- PKHD1L1 | c.7930G>C p.A2644P | Missense Mutation (SNP) | VAF 71/149 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs1464450784; called by muse, mutect2, varscan2
- PNMA8B | c.1613C>T p.A538V | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV66535695; called by muse, mutect2, varscan2
- PPIL3 | c.463C>T p.H155Y (on ENST00000392283 / NM_130906.3; = p.H159Y on NM_032472.4) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs1325902997; called by muse, mutect2
- PREX1 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV64251747; called by muse, mutect2, varscan2
- QTRT2 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 70/139 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV55559228; called by muse, mutect2, varscan2
- RAB11FIP5 | c.1272G>T p.E424D | Missense Mutation (SNP) | VAF 42/310 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV99242018; called by muse, mutect2, varscan2
- RALYL | c.76G>C p.G26R | Missense Mutation (SNP) | VAF 63/156 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72818856; called by muse, mutect2, varscan2
- RFC1 | c.659A>G p.H220R | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1214931015; called by muse, mutect2, varscan2
- RNF115 | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 66/216 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1408107147; called by muse, mutect2, varscan2
- RNF151 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as rs749042000, COSV100364423; called by muse, mutect2, varscan2
- SEPTIN14 | c.853C>G p.R285G | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66426763; called by muse, varscan2
- SGSM2 | c.1117C>T p.P373S | Missense Mutation (SNP) | VAF 38/232 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1333364926; called by muse, mutect2, varscan2
- SI | c.4062+1G>T p.X1354_splice | Splice Site (SNP) | VAF 64/103 reads (62%) | catalogued as COSV100017400; called by muse, varscan2
- SLC2A13 | c.1105G>C p.V369L | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as rs770794073; called by muse, mutect2, varscan2
- SLITRK3 | c.2476C>A p.Q826K | Missense Mutation (SNP) | VAF 283/436 reads (65%) | SIFT tolerated (1); PolyPhen possibly damaging (0.857); catalogued as COSV53851386; called by muse, mutect2, varscan2
- TDP2 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as rs1211200558, COSV61967304; called by muse, mutect2, varscan2
- TESPA1 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.996); catalogued as rs1262243069; called by muse, mutect2, varscan2
- TEX44 | c.949G>C p.V317L | Missense Mutation (SNP) | VAF 48/245 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.476); catalogued as rs1277756642; called by muse, mutect2, varscan2
- TLNRD1 | c.394C>G p.L132V | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs747927954, COSV51256815, COSV51257583; called by muse, mutect2, varscan2
- U2AF2 | c.526G>T p.G176W | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.764); catalogued as COSV100454029, COSV58276374; called by muse, mutect2, varscan2
- UBC | c.1918G>C p.D640H | Missense Mutation (SNP) | VAF 208/774 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV60058996; called by muse, varscan2
- UNC45B | c.1157A>C p.K386T | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.023); catalogued as rs1010493460, COSV52096198; called by muse, varscan2
- VPS9D1 | c.1814G>A p.G605E | Missense Mutation (SNP) | VAF 54/321 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs952281021, COSV66995025; called by muse, mutect2, varscan2
- WIPF1 | c.1453C>T p.R485W | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1041727019; called by muse, varscan2
- ZAN | c.3540C>A p.Y1180* | Nonsense Mutation (SNP) | VAF 65/291 reads (22%) | catalogued as rs1447501376; called by muse, mutect2, varscan2
- ZAR1L | c.506C>A p.P169Q | Missense Mutation (SNP) | VAF 57/278 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as COSV61526184; called by muse, mutect2, varscan2
- ZMAT4 | c.64C>G p.Q22E | Missense Mutation (SNP) | VAF 88/353 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1327604602; called by muse, mutect2, varscan2
- ZNF423 | c.2716G>T p.E906* (on ENST00000563137 / NM_001379286.1; = p.E898* on NM_015069.4) | Nonsense Mutation (SNP) | VAF 115/294 reads (39%) | catalogued as rs1555514965; called by muse, mutect2, varscan2
- ZNF423 | c.2621C>A p.P874H (on ENST00000563137 / NM_001379286.1; = p.P866H on NM_015069.4) | Missense Mutation (SNP) | VAF 45/232 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.179); catalogued as COSV52181896; called by muse, mutect2, varscan2
- ZNF558 | c.730G>T p.V244F | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as COSV104399150; called by muse, varscan2
- ZWILCH | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 38/269 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.127); catalogued as rs1257357493, COSV100329014; called by muse, mutect2, varscan2
- AC100868.1 | c.1250C>A p.T417K | Missense Mutation (SNP) | VAF 52/536 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ACKR1 | c.502G>T p.G168W | Missense Mutation (SNP) | VAF 114/306 reads (37%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACTC1 | c.1079G>T p.S360I | Missense Mutation (SNP) | VAF 50/364 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ADGRG4 | c.4041C>A p.N1347K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ALDH8A1 | c.287-2A>T p.X96_splice | Splice Site (SNP) | VAF 16/88 reads (18%) | called by muse, varscan2
- ALPK2 | c.1461G>A p.M487I | Missense Mutation (SNP) | VAF 77/192 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ARHGEF12 | c.1586T>C p.V529A | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.428); called by mutect2, varscan2
- ARID1B | c.4399G>T p.G1467C | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ATG4D | c.1245C>A p.V415= | Splice Region (SNP) | VAF 44/91 reads (48%) | called by muse, mutect2
- ATP6V1E1 | c.34A>T p.I12L | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- BMP7 | c.1193C>T p.P398L | Missense Mutation (SNP) | VAF 237/756 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C11orf86 | c.80C>A p.P27H | Missense Mutation (SNP) | VAF 343/832 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- C3orf84 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 109/237 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CADPS | c.1845G>T p.W615C | Missense Mutation (SNP) | VAF 58/337 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CAPG | c.217G>T p.E73* | Nonsense Mutation (SNP) | VAF 128/328 reads (39%) | called by muse, mutect2, varscan2
- CARMIL1 | c.102_103delinsT p.L34Ffs*23 | Frame Shift Del (DEL) | VAF 14/61 reads (23%) | called by pindel, varscan2*
- CCDC38 | c.1602T>A p.H534Q | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, varscan2
- CCNB3 | c.934G>T p.A312S | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CFHR2 | c.800G>T p.C267F | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CHMP4B | c.398A>G p.Q133R | Missense Mutation (SNP) | VAF 121/392 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- COL3A1 | c.533C>A p.P178H | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- COL6A5 | c.2605A>T p.N869Y | Missense Mutation (SNP) | VAF 112/208 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- COMMD1 | c.253G>T p.G85W | Missense Mutation (SNP) | VAF 57/259 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- CSRNP3 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 76/188 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- CTC1 | c.1012A>T p.S338C | Missense Mutation (SNP) | VAF 55/251 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- CYP2W1 | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- DBNDD2 | c.29T>G p.L10W | Missense Mutation (SNP) | VAF 43/232 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- DDX3Y | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.985); called by muse, varscan2
- DHX58 | c.1086C>A p.F362L | Missense Mutation (SNP) | VAF 66/326 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- DIPK1C | c.650G>T p.G217V | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLG2 | c.115C>A p.P39T | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- DLGAP1 | c.1513G>T p.D505Y | Missense Mutation (SNP) | VAF 167/545 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- DMRT1 | c.556C>A p.Q186K | Missense Mutation (SNP) | VAF 102/278 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- DMRTA2 | c.159del p.P54Rfs*161 | Frame Shift Del (DEL) | VAF 91/457 reads (20%) | called by mutect2, pindel, varscan2
- DNAH17 | c.8435G>T p.R2812L | Missense Mutation (SNP) | VAF 113/453 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH7 | c.10588G>T p.V3530L | Missense Mutation (SNP) | VAF 62/226 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- DOCK3 | c.4174A>T p.S1392C | Missense Mutation (SNP) | VAF 92/237 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- DYNC1I1 | c.794G>T p.G265V | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- EFEMP1 | c.1367C>T p.S456L | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- EVC | c.1931C>A p.S644* | Nonsense Mutation (SNP) | VAF 233/614 reads (38%) | called by muse, mutect2, varscan2
- F2 | c.904G>C p.G302R | Missense Mutation (SNP) | VAF 265/607 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM9A | c.10G>A p.V4M | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- FER1L6 | c.4389G>C p.E1463D | Missense Mutation (SNP) | VAF 82/233 reads (35%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.767); called by muse, mutect2
- FHOD3 | c.1190G>T p.R397L | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FOXP2 | c.424C>T p.Q142* | Nonsense Mutation (SNP) | VAF 145/478 reads (30%) | called by muse, mutect2, varscan2
- FRAT1 | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2
- FREM3 | c.6107G>C p.R2036T | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FRY | c.5999G>C p.S2000T | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FSIP2 | c.9600C>G p.Y3200* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2, varscan2
- GRK5 | c.1293G>T p.R431S | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); called by muse, varscan2
- GRK5 | c.1383G>T p.L461F | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.037); called by muse, varscan2
- GRK5 | c.1384G>T p.D462Y | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, varscan2
- GRM1 | c.1984C>A p.L662I | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- HAPLN4 | c.667G>T p.V223L | Missense Mutation (SNP) | VAF 120/308 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- HECTD4 | c.9310G>C p.V3104L | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- HECW2 | c.1429G>T p.G477C | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- HELZ2 | c.4505G>T p.R1502L (on ENST00000467148 / NM_001037335.2; = p.R933L on NM_033405.3) | Missense Mutation (SNP) | VAF 125/346 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- HELZ2 | c.3474G>T p.R1158S (on ENST00000467148 / NM_001037335.2; = p.R589S on NM_033405.3) | Missense Mutation (SNP) | VAF 55/393 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- HIF3A | c.1207G>T p.A403S (on ENST00000377670 / NM_152795.4; = p.A334S on NM_022462.4) | Missense Mutation (SNP) | VAF 98/233 reads (42%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- HOXA11 | c.197C>G p.A66G | Missense Mutation (SNP) | VAF 139/445 reads (31%) | SIFT tolerated (1); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- HTR1E | c.162C>A p.H54Q | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- IGKV2-28 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by mutect2, varscan2
- IGLV10-54 | c.184C>A p.H62N | Missense Mutation (SNP) | VAF 135/484 reads (28%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGLV8-61 | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 57/288 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ILKAP | c.703G>T p.G235* | Nonsense Mutation (SNP) | VAF 16/83 reads (19%) | called by muse, mutect2, varscan2
- JAK3 | c.194C>A p.P65H | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JAK3 | c.193C>A p.P65T | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KALRN | c.8804A>C p.H2935P (on ENST00000360013 / NM_001024660.4; = p.H1238P on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 294/488 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- KCNC4 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 45/263 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF1A | c.998C>G p.P333R | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KNG1 | c.1185A>C p.E395D | Missense Mutation (SNP) | VAF 67/92 reads (73%) | SIFT tolerated (0.21); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- KPNA7 | c.812G>T p.G271V | Missense Mutation (SNP) | VAF 183/707 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- LCTL | c.143C>G p.S48C | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LILRA6 | c.7C>A p.P3T | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- LRFN5 | c.1174_1182del p.P392_S394del | In Frame Del (DEL) | VAF 33/68 reads (49%) | called by mutect2, pindel, varscan2
- MAGEL2 | c.1636C>G p.P546A | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated, low confidence (0.09); called by muse, mutect2, varscan2
- MARCHF11 | c.779C>A p.T260N | Missense Mutation (SNP) | VAF 79/163 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- MFSD10 | c.705C>G p.I235M | Missense Mutation (SNP) | VAF 54/284 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- MTUS2 | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- MUC4 | c.7364C>T p.S2455F | Missense Mutation (SNP) | VAF 512/2617 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.496); called by muse, varscan2
- MUC4 | c.5255C>G p.S1752* | Nonsense Mutation (SNP) | VAF 500/2084 reads (24%) | called by muse, varscan2
- MYH8 | c.3519G>C p.E1173D | Missense Mutation (SNP) | VAF 97/540 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- MYLK3 | c.369G>T p.R123S | Missense Mutation (SNP) | VAF 227/518 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- MYO15A | c.9626C>T p.S3209F | Missense Mutation (SNP) | VAF 107/608 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- MYO7A | c.4001G>A p.G1334D | Missense Mutation (SNP) | VAF 287/676 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NDST4 | c.1453T>C p.Y485H | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- NFE2L2 | c.1004G>A p.S335N | Missense Mutation (SNP) | VAF 58/152 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NRAP | c.824T>A p.M275K | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- NUDT5 | c.118A>T p.T40S | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, varscan2
- OPRD1 | c.1069G>T p.V357F | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.546); called by muse, mutect2
- OR13A1 | c.693G>A p.M231I | Missense Mutation (SNP) | VAF 82/385 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR2T3 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 42/226 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- OR51F1 | c.420G>T p.R140S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- OR51G2 | c.838G>A p.V280I | Missense Mutation (SNP) | VAF 103/248 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OTX1 | c.892C>A p.H298N | Missense Mutation (SNP) | VAF 46/351 reads (13%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.775); called by mutect2, varscan2
- PACSIN1 | c.295C>T p.Q99* | Nonsense Mutation (SNP) | VAF 102/642 reads (16%) | called by muse, mutect2, varscan2
- PARP14 | c.1269G>T p.L423F | Missense Mutation (SNP) | VAF 59/103 reads (57%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- PCDH19 | c.2349G>T p.K783N (on ENST00000373034 / NM_001184880.2; = p.K736N on NM_020766.3) | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- PCDHA4 | c.2171C>G p.S724C | Missense Mutation (SNP) | VAF 164/433 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- PCDHGB6 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PIGL | c.246C>A p.Y82* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2
- PLCL2 | c.1675G>T p.D559Y (on ENST00000615277 / NM_001144382.2; = p.D433Y on NM_015184.5) | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PLEKHG1 | c.1985A>G p.D662G | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PNCK | c.623G>T p.G208V (on ENST00000340888 / NM_001366975.1; = p.G291V on NM_001039582.3) | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- POU2F1 | c.553C>T p.Q185* (on ENST00000541643 / NM_001365848.1; = p.Q208* on NM_002697.4) | Nonsense Mutation (SNP) | VAF 63/270 reads (23%) | called by muse, mutect2, varscan2
- POU3F3 | c.94G>A p.G32S | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP1R16B | c.439A>G p.I147V | Missense Mutation (SNP) | VAF 77/223 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PRCP | c.1021G>A p.V341M | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- PRRT1 | c.919T>A p.*307Kext*107 | Nonstop Mutation (SNP) | VAF 175/403 reads (43%) | called by muse, mutect2, varscan2
- PTPRK | c.345G>T p.Q115H | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- PYROXD2 | c.1339G>T p.A447S | Missense Mutation (SNP) | VAF 68/220 reads (31%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- QRICH2 | c.446A>G p.Q149R | Missense Mutation (SNP) | VAF 156/379 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- RALA | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RIMS1 | c.3793A>T p.S1265C | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- RNF115 | c.235del p.D79Ifs*13 | Frame Shift Del (DEL) | VAF 83/231 reads (36%) | called by mutect2, pindel, varscan2
- RTL1 | c.1858G>T p.G620C | Missense Mutation (SNP) | VAF 42/217 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- RYR1 | c.451C>A p.P151T | Missense Mutation (SNP) | VAF 214/512 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RYR2 | c.11823G>T p.W3941C | Missense Mutation (SNP) | VAF 53/168 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SACS | c.2421A>G p.I807M | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SCN10A | c.5776A>G p.R1926G | Missense Mutation (SNP) | VAF 97/241 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SEC61A1 | c.195G>A p.M65I | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SENP7 | c.2485G>T p.A829S | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- SERPINC1 | c.1334G>C p.R445T | Missense Mutation (SNP) | VAF 96/283 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SGCZ | c.700G>T p.A234S | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- SH3RF3 | c.781G>T p.G261* | Nonsense Mutation (SNP) | VAF 227/521 reads (44%) | called by muse, mutect2, varscan2
- SIPA1L2 | c.3808G>T p.A1270S | Missense Mutation (SNP) | VAF 211/512 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SLC38A10 | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 101/274 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC45A2 | c.892C>G p.R298G | Missense Mutation (SNP) | VAF 103/602 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC4A4 | c.435G>T p.W145C (on ENST00000264485 / NM_001098484.3; = p.W101C on NM_003759.4) | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLCO1B1 | c.1130T>C p.L377S | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- SNX25 | c.140A>T p.H47L | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SPATA48 | c.211C>A p.P71T | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- SPP1 | c.473G>T p.G158V (on ENST00000395080 / NM_001040058.2; = p.G144V on NM_000582.2) | Missense Mutation (SNP) | VAF 25/219 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SSRP1 | c.1582G>C p.D528H | Missense Mutation (SNP) | VAF 64/158 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- ST6GALNAC1 | c.777G>C p.E259D | Missense Mutation (SNP) | VAF 24/107 reads (22%) | PolyPhen probably damaging (0.987); called by muse, varscan2
- STAM | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- STK11 | c.619del p.D207Tfs*80 | Frame Shift Del (DEL) | VAF 45/133 reads (34%) | called by mutect2, pindel, varscan2
- SYN2 | c.1529C>G p.A510G | Missense Mutation (SNP) | VAF 65/217 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TACR3 | c.866A>T p.E289V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- TBC1D14 | c.1294C>T p.R432* | Nonsense Mutation (SNP) | VAF 83/299 reads (28%) | called by muse, mutect2, varscan2
- TBC1D23 | c.139G>T p.A47S | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.47); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- TDRD6 | c.5383G>T p.G1795C | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- TEAD3 | c.1103G>A p.C368Y | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM117 | c.487G>C p.G163R | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNRC6A | c.1805G>C p.G602A | Missense Mutation (SNP) | VAF 58/183 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- TNS3 | c.1692G>T p.Q564H | Missense Mutation (SNP) | VAF 75/205 reads (37%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.459); called by mutect2, varscan2
- TNS3 | c.1690_1691insT p.Q564Lfs*39 | Frame Shift Ins (INS) | VAF 74/208 reads (36%) | called by mutect2, pindel*, varscan2
- TPSD1 | c.199G>T p.G67W | Missense Mutation (SNP) | VAF 102/334 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TRMT44 | c.2132C>G p.S711C | Missense Mutation (SNP) | VAF 81/445 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- TRPA1 | c.1456C>G p.L486V | Missense Mutation (SNP) | VAF 27/274 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TSHZ2 | c.606C>A p.S202R | Missense Mutation (SNP) | VAF 44/211 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- TTC21B | c.3541A>T p.K1181* | Nonsense Mutation (SNP) | VAF 105/294 reads (36%) | called by muse, mutect2, varscan2
- TTC28 | c.1420G>T p.G474W | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- TXNDC16 | c.339A>T p.E113D | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.701); called by muse, mutect2
- UCK2 | c.500-2A>C p.X167_splice | Splice Site (SNP) | VAF 38/106 reads (36%) | called by muse, mutect2, varscan2
- UGT2B11 | c.865C>A p.P289T | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- UPK1A | c.321G>T p.E107D | Missense Mutation (SNP) | VAF 95/264 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- URB1 | c.2156C>T p.S719F | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- USP34 | c.4777A>T p.S1593C | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- VCAN | c.202A>T p.K68* | Nonsense Mutation (SNP) | VAF 47/288 reads (16%) | called by muse, mutect2, varscan2
- VSIG8 | c.1093T>G p.C365G | Missense Mutation (SNP) | VAF 114/320 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- ZFHX4 | c.473G>T p.S158I | Missense Mutation (SNP) | VAF 109/723 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- ZFHX4 | c.2039G>T p.G680V | Missense Mutation (SNP) | VAF 87/432 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ZNF248 | c.1658G>T p.C553F | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AFG3L2 | c.1461C>T p.F487= | Silent (SNP) | VAF 106/323 reads (33%) | catalogued as rs779230346; called by muse, mutect2, varscan2
- AKAP12 | c.1587T>A p.S529= | Silent (SNP) | VAF 38/167 reads (23%) | called by muse, mutect2, varscan2
- ANK1 | c.5148T>A p.A1716= | Silent (SNP) | VAF 77/249 reads (31%) | called by muse, mutect2
- ANK1 | c.1653G>T p.V551= | Silent (SNP) | VAF 117/505 reads (23%) | called by muse, mutect2, varscan2
- AQP12B | c.84G>T p.L28= | Silent (SNP) | VAF 115/532 reads (22%) | called by muse, mutect2, varscan2
- ASAP1 | c.2511C>G p.T837= | Silent (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- ASTN1 | c.660C>A p.A220= | Silent (SNP) | VAF 84/350 reads (24%) | called by mutect2, varscan2
- BCL11A | c.90A>G p.E30= | Silent (SNP) | VAF 28/224 reads (13%) | called by mutect2, varscan2
- BFSP1 | c.1521C>T p.D507= | Silent (SNP) | VAF 38/214 reads (18%) | catalogued as rs780034931, COSV64901543; called by muse, mutect2
- C8B | c.384A>C p.A128= | Silent (SNP) | VAF 83/419 reads (20%) | called by muse, mutect2, varscan2
- CASQ2 | c.243C>A p.A81= | Silent (SNP) | VAF 79/261 reads (30%) | called by muse, mutect2, varscan2
- CCDC61 | c.288G>T p.R96= | Silent (SNP) | VAF 40/123 reads (33%) | called by muse, mutect2, varscan2
- CLNK | c.1263C>A p.L421= | Silent (SNP) | VAF 21/137 reads (15%) | called by muse, mutect2, varscan2
- CNGB3 | c.813C>A p.I271= | Silent (SNP) | VAF 88/200 reads (44%) | called by muse, mutect2, varscan2
- CRLS1 | c.243C>T p.A81= | Silent (SNP) | VAF 39/233 reads (17%) | called by muse, mutect2, varscan2
- CSMD3 | c.1047C>A p.T349= | Silent (SNP) | VAF 88/215 reads (41%) | catalogued as COSV99827901; called by muse, mutect2, varscan2
- CYP21A2 | c.648C>T p.L216= | Silent (SNP) | VAF 72/562 reads (13%) | called by mutect2, varscan2
- DISP3 | c.255C>G p.P85= | Silent (SNP) | VAF 170/459 reads (37%) | called by muse, mutect2, varscan2
- DLGAP2 | c.345C>T p.D115= | Silent (SNP) | VAF 22/246 reads (9%) | catalogued as rs780412370, COSV70104356; called by muse, mutect2
- DOCK5 | c.546C>T p.A182= | Silent (SNP) | VAF 81/349 reads (23%) | called by muse, mutect2, varscan2
- EFCAB12 | c.546C>T p.P182= | Silent (SNP) | VAF 22/192 reads (11%) | catalogued as rs762069785; called by muse, mutect2, varscan2
- ESCO2 | c.1113A>G p.T371= | Silent (SNP) | VAF 28/124 reads (23%) | called by muse, mutect2, varscan2
- FAM13C | c.888C>G p.L296= | Silent (SNP) | VAF 80/291 reads (27%) | called by muse, mutect2, varscan2
- FAM178B | c.156C>T p.A52= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs759069690, COSV100013930, COSV59972727; called by muse, mutect2
- FAM214A | c.2769C>T p.F923= | Silent (SNP) | VAF 29/130 reads (22%) | called by muse, mutect2, varscan2
- FIGN | c.1986A>T p.I662= | Silent (SNP) | VAF 142/326 reads (44%) | called by muse, mutect2, varscan2
- FYB1 | c.1704G>A p.E568= | Silent (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- GAREM1 | c.2586G>T p.V862= (on ENST00000269209 / NM_001242409.2; = p.V861= on NM_022751.3) | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as rs779968087; called by muse, mutect2, varscan2
- GRIK2 | c.144C>T p.G48= | Silent (SNP) | VAF 16/81 reads (20%) | called by muse, mutect2, varscan2
- HELZ2 | c.597G>A p.L199= | Silent (SNP) | VAF 25/141 reads (18%) | called by muse, mutect2, varscan2
- IGLV10-54 | c.183C>A p.G61= | Silent (SNP) | VAF 137/482 reads (28%) | called by muse, mutect2, varscan2
- INSM1 | c.1389G>A p.L463= | Silent (SNP) | VAF 147/444 reads (33%) | called by muse, mutect2, varscan2
- JAK3 | c.1587T>C p.H529= | Silent (SNP) | VAF 108/228 reads (47%) | catalogued as COSV71687800; called by muse, mutect2, varscan2
- KDM1B | c.1083C>A p.L361= (on ENST00000449850; = p.L229= on NM_153042.4) | Silent (SNP) | VAF 10/111 reads (9%) | called by muse, mutect2
- KDM3A | c.669C>T p.V223= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV57221947; called by muse, mutect2, varscan2
- KRT10 | c.1329G>A p.E443= | Silent (SNP) | VAF 112/302 reads (37%) | called by muse, mutect2, varscan2
- KRT77 | c.1272G>A p.A424= | Silent (SNP) | VAF 219/406 reads (54%) | catalogued as rs764733603, COSV59238613; called by muse, mutect2, varscan2
- LAT2 | c.165C>A p.S55= | Silent (SNP) | VAF 118/532 reads (22%) | called by muse, mutect2, varscan2
- LINGO1 | c.762C>G p.T254= | Silent (SNP) | VAF 97/239 reads (41%) | called by muse, mutect2, varscan2
- LRP12 | c.768G>T p.V256= | Silent (SNP) | VAF 95/148 reads (64%) | called by muse, mutect2, varscan2
- LRP1B | c.13377C>A p.T4459= | Silent (SNP) | VAF 12/45 reads (27%) | called by muse, varscan2
- LYSMD1 | c.570C>G p.L190= | Silent (SNP) | VAF 155/369 reads (42%) | called by muse, mutect2, varscan2
- MAGEL2 | c.1635C>A p.A545= | Silent (SNP) | VAF 11/49 reads (22%) | called by mutect2, varscan2
- MED24 | c.804G>A p.T268= | Silent (SNP) | VAF 85/336 reads (25%) | catalogued as rs748596445, COSV62418456; called by muse, mutect2, varscan2
- MINK1 | c.3387C>T p.F1129= | Silent (SNP) | VAF 35/160 reads (22%) | called by muse, mutect2, varscan2
- MYO18B | c.804C>A p.P268= | Silent (SNP) | VAF 13/54 reads (24%) | called by muse, mutect2
- NCK2 | c.522G>A p.A174= | Silent (SNP) | VAF 25/196 reads (13%) | catalogued as rs752440879; called by muse, mutect2, varscan2
- NECAB2 | c.897G>A p.L299= | Silent (SNP) | VAF 138/348 reads (40%) | catalogued as rs768645918, COSV59420450; called by muse, mutect2, varscan2
- NKD2 | c.450C>T p.T150= | Silent (SNP) | VAF 34/253 reads (13%) | called by muse, mutect2, varscan2
- OR10G8 | c.801G>T p.V267= | Silent (SNP) | VAF 124/268 reads (46%) | called by muse, mutect2, varscan2
- PCDHB10 | c.825G>C p.A275= | Silent (SNP) | VAF 83/231 reads (36%) | called by muse, mutect2, varscan2
- PDGFC | c.864C>T p.L288= | Silent (SNP) | VAF 24/164 reads (15%) | catalogued as rs1178355272; called by muse, mutect2, varscan2
- PKHD1L1 | c.4926T>C p.T1642= | Silent (SNP) | VAF 43/109 reads (39%) | called by muse, mutect2, varscan2
- POP1 | c.2400G>T p.G800= | Silent (SNP) | VAF 75/175 reads (43%) | called by muse, mutect2, varscan2
- PROX2 | c.480T>A p.A160= | Silent (SNP) | VAF 167/300 reads (56%) | called by muse, mutect2, varscan2
- PTCHD4 | c.2340G>T p.L780= | Silent (SNP) | VAF 10/80 reads (13%) | called by muse, mutect2, varscan2
- RBFOX3 | c.852C>T p.S284= | Silent (SNP) | VAF 35/288 reads (12%) | catalogued as rs551189632, COSV101332210; called by muse, mutect2, varscan2
- RELN | c.1564T>C p.L522= | Silent (SNP) | VAF 42/132 reads (32%) | called by muse, varscan2
- RPS6KB2 | c.810C>T p.T270= | Silent (SNP) | VAF 39/261 reads (15%) | catalogued as rs767711171; called by muse, mutect2, varscan2
- SALL1 | c.3720G>T p.A1240= | Silent (SNP) | VAF 171/383 reads (45%) | catalogued as rs185996794, COSV51757256, COSV99171462; called by muse, mutect2, varscan2
- SCRT1 | c.93C>T p.L31= | Silent (SNP) | VAF 85/147 reads (58%) | called by muse, mutect2, varscan2
- SORCS1 | c.18C>A p.A6= | Silent (SNP) | VAF 17/41 reads (41%) | called by muse, mutect2, varscan2
- ST3GAL3 | c.1038A>T p.A346= (on ENST00000361392 / NM_174964.4; = p.A331= on NM_006279.5) | Silent (SNP) | VAF 129/463 reads (28%) | called by muse, mutect2, varscan2
- SYT9 | c.1095G>T p.T365= | Silent (SNP) | VAF 49/135 reads (36%) | catalogued as rs767582960; called by muse, mutect2, varscan2
- TBC1D8B | c.3189G>A p.E1063= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV99344800; called by muse, varscan2
- TFF2 | c.312G>T p.R104= | Silent (SNP) | VAF 88/240 reads (37%) | called by muse, mutect2, varscan2
- TLE4 | c.1173G>T p.A391= | Silent (SNP) | VAF 106/270 reads (39%) | catalogued as COSV99511319; called by mutect2, varscan2
- TPPP | c.534G>A p.E178= | Silent (SNP) | VAF 113/516 reads (22%) | called by muse, mutect2, varscan2
- TSHZ2 | c.2367G>A p.K789= | Silent (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
- TTC27 | c.27G>T p.L9= | Silent (SNP) | VAF 114/264 reads (43%) | called by muse, mutect2, varscan2
- UBC | c.489G>A p.K163= | Silent (SNP) | VAF 265/998 reads (27%) | called by muse, mutect2, varscan2
- UPRT | c.865T>C p.L289= | Silent (SNP) | VAF 20/46 reads (43%) | called by muse, mutect2, varscan2
- VPS13C | c.8271C>T p.V2757= (on ENST00000644861 / NM_020821.3; = p.V2714= on NM_017684.5) | Silent (SNP) | VAF 17/89 reads (19%) | called by muse, mutect2, varscan2
- WDR6 | c.1044A>T p.P348= | Silent (SNP) | VAF 82/213 reads (38%) | called by muse, mutect2, varscan2
- ZNF470 | c.1515A>G p.G505= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as rs1406063122; called by muse, mutect2, varscan2
- ZNF668 | c.1338G>A p.P446= | Silent (SNP) | VAF 92/336 reads (27%) | catalogued as rs200605496; called by muse, mutect2, varscan2
- AC009237.3 | n.556G>T | RNA (SNP) | VAF 37/221 reads (17%) | called by muse, mutect2, varscan2
- ADAM6 | n.986C>A | RNA (SNP) | VAF 49/196 reads (25%) | called by muse, mutect2, varscan2
- ALS2 | c.-45C>A | 5'UTR (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2, varscan2
- ARMC4 | c.*56C>A | 3'UTR (SNP) | VAF 39/115 reads (34%) | called by muse, mutect2, varscan2
- AS3MT | c.-22C>T | 5'UTR (SNP) | VAF 34/270 reads (13%) | called by muse, varscan2
- ASL | c.602+72T>A | Intron (SNP) | VAF 46/164 reads (28%) | called by muse, varscan2
- BCKDHB | c.*43C>T | 3'UTR (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2, varscan2
- C12orf66 | chr12:64187586 C>A | 3'Flank (SNP) | VAF 54/83 reads (65%) | called by muse, mutect2, varscan2
- CARTPT | c.160-22G>T | Intron (SNP) | VAF 185/562 reads (33%) | called by muse, mutect2, varscan2
- CCDC60 | c.170+4842C>A | Intron (SNP) | VAF 84/142 reads (59%) | called by muse, varscan2
- CD300LG | c.885+354C>G | Intron (SNP) | VAF 78/247 reads (32%) | called by muse, varscan2
- CEP120 | c.1039-159G>C | Intron (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2, varscan2
- CEP170P1 | n.4414C>T | RNA (SNP) | VAF 21/216 reads (10%) | called by muse, mutect2, varscan2
- CYB5RL | chr1:54171114 G>C | 3'Flank (SNP) | VAF 71/169 reads (42%) | called by muse, mutect2, varscan2
- DPYD | c.*17G>T | 3'UTR (SNP) | VAF 26/214 reads (12%) | called by muse, mutect2, varscan2
- EI24P4 | n.919G>T | RNA (SNP) | VAF 149/516 reads (29%) | catalogued as rs1330809003; called by muse, mutect2, varscan2
- GATA3 | c.-66G>A | 5'UTR (SNP) | VAF 103/397 reads (26%) | called by muse, mutect2, varscan2
- GUSBP10 | n.203G>T | RNA (SNP) | VAF 30/186 reads (16%) | catalogued as rs142310593; called by muse, mutect2
- HSP90AB3P | n.1919A>T | RNA (SNP) | VAF 170/620 reads (27%) | called by muse, mutect2, varscan2
- IRX1 | c.*1T>G | 3'UTR (SNP) | VAF 253/519 reads (49%) | called by muse, mutect2, varscan2
- MIR424 | chrX:134546563 C>G | 3'Flank (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2, varscan2
- MMP26 | c.-145+92406G>T | Intron (SNP) | VAF 89/211 reads (42%) | called by muse, mutect2, varscan2
- MRPL20 | chr1:1399685 G>A | 3'Flank (SNP) | VAF 47/234 reads (20%) | called by muse, mutect2, varscan2
- MUC5B | c.*252C>A | 3'UTR (SNP) | VAF 66/159 reads (42%) | called by muse, mutect2, varscan2
- NRXN1 | c.820+33C>A | Intron (SNP) | VAF 24/285 reads (8%) | called by muse, mutect2
- OR10AB1P | n.953del | RNA (DEL) | VAF 60/154 reads (39%) | called by mutect2, pindel, varscan2
- OR2M1P | n.283G>C | RNA (SNP) | VAF 49/260 reads (19%) | called by muse, mutect2, varscan2
- P4HA3 | c.*131G>A | 3'UTR (SNP) | VAF 68/752 reads (9%) | catalogued as rs533764229, COSV59041962; called by muse, mutect2
- PBK | c.596-31C>T | Intron (SNP) | VAF 31/130 reads (24%) | catalogued as rs934026167; called by muse, varscan2
- PCDH1 | c.41-116C>T | Intron (SNP) | VAF 67/203 reads (33%) | called by muse, mutect2, varscan2
- PDX1 | c.*8G>C | 3'UTR (SNP) | VAF 30/151 reads (20%) | called by muse, mutect2, varscan2
- PIK3CD | c.-138+2547C>A | Intron (SNP) | VAF 235/653 reads (36%) | called by muse, mutect2, varscan2
- RRAS2 | c.109-12449C>T | Intron (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2
- SCN1B | c.-18A>G | 5'UTR (SNP) | VAF 19/103 reads (18%) | called by muse, mutect2
- SIRPB2 | c.-58C>A | 5'UTR (SNP) | VAF 30/106 reads (28%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-12749T>C | Intron (SNP) | VAF 7/24 reads (29%) | called by mutect2, varscan2
- SYT14 | c.*426T>A | 3'UTR (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2
- TEX51 | c.274+9G>T | Intron (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2
- TOR1AIP2 | c.-146-12146C>G | Intron (SNP) | VAF 40/104 reads (38%) | called by muse, varscan2
- TRIM67 | chr1:231217867 del GTGGCCTCTTTCAGAAAAAAGTTCCCTGAAGTCCA | 3'Flank (DEL) | VAF 20/172 reads (12%) | called by mutect2, pindel
- TSEN54 | c.221+13G>T | Intron (SNP) | VAF 103/270 reads (38%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.5544+142G>C | Intron (SNP) | VAF 36/137 reads (26%) | called by muse, mutect2, varscan2
- UBE2DNL | n.271C>T | RNA (SNP) | VAF 33/84 reads (39%) | called by muse, mutect2, varscan2
- UBE2V2 | c.16+26A>G | Intron (SNP) | VAF 81/794 reads (10%) | called by muse, mutect2
- UNC5D | c.*2475A>T | 3'UTR (SNP) | VAF 4/31 reads (13%) | called by muse, mutect2
- UQCRB | c.*2076A>T | 3'UTR (SNP) | VAF 50/106 reads (47%) | called by muse, mutect2, varscan2
- Unknown | chr16:27290268 G>T | IGR (SNP) | VAF 59/259 reads (23%) | called by muse, mutect2, varscan2
- XYLT2 | chr17:50363056 A>C | 3'Flank (SNP) | VAF 24/121 reads (20%) | called by muse, mutect2, varscan2
